Surgical pathology report (de-identified scan), TCGA case TCGA-66-2791, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Indivumed, specimen TCGA-66-2791-01A (Primary Tumor).

[page 1 of 2]
Material examined:

Right lung

Clinical diagnosis and question

Bronchial carcinoma right central lower lobe, large-cell carcinoma

REPORT ON FINDINGS**Macroscopy**

- 1.) Right lung: inflated, fixed right lung measuring 14 x 12 cm at the base and up to 26 cm high, central bronchus resection plane located 1 cm upstream of the upper lobe bronchus. Dorsomedial and basal pleura over S10 shows an area of max. 7.5 x 4 cm with roughening or residual adhesion, in the basal region over S7 is a 3 cm similar area, Intermediate bronchus in the region of the middle lobe bronchus bifurcation and proximal sections of the bronchi of the basal group narrowed by a moderately firm, predominantly pale brownish-white tumor with small patches of grayish-black pigmentation, max. 4.7 cm in size, with unclear and arcuate demarcation, with the main mass in S10 and adjacent sections of S6, S7 and S9, extending to within 0.2 cm of the medial visceral pleura over S10. Truncation of B9 and B10 and also a subsegmental branch of B7 in the tumor. Focal crossing of lower pleural fissure and infiltration of middle lobe. In the tumor environment some satellite foci up to 0.2 cm in size. Peripheral sections of basal bronchial branches dilated and filled with thick mucus. Parenchyma below the adhesion zone over S10 shows diffuse induration and a brown vitreous appearance. In the mediocaudal region of the upper lobe bronchus bifurcation next to the pulmonary artery a 2.5 cm node firmly adherent to the vascular wall with predominantly whitish section surfaces and extension right up to the hilar resection surface, not continuity with tumor. At the intermediate bronchus a 0.7 cm node part suggestive of a tumor, next to the lower lobe bronchus part a 0.5 cm grayish-black node. Apical parenchyma in S1 shows a seam-like area of induration and grayish-brown discoloration up to 0.4 cm wide.
- 2.) Paraesophageal LN (station 8): 1.2 cm node.
- 3.) Low paratracheal LN (station 4) right: 1.4 cm node part with abundant surrounding tissue.
- 4.) High paratracheal LN (station 2) right: 1.4 cm node with abundant surrounding tissue and in parts whitish section surfaces suggestive of tumor.
- 5.) Subcarinal LN (station 7): 3.8 cm node with some surrounding tissue and in parts whitish section surfaces suggestive of tumor.
- 6.) Hilar LN (station 10) left: 1.2 cm node part and a 0.9 cm lesioned node.

Examined:

- 1.) a: Tumor with rest of parenchyma and satellite focus, b: tumor with B10, c: 2 sections of tumor with pleura, d: lower pleural fissure (middle lobe part color-marked), e: node at upper lobe bronchus bifurcation with hilar resection surface (color-marked), f: S10 mediobasal, g: S1 apical and node part intermediate bronchus, h: central bronchus resection plane and resection margins of vessels and also node at lower lobe bronchus,
- 2.), 3.) + 6.) All material (in 3.) lamellated),
- 4.) Node (lamellated),
- 5.) 2 sections,
- 13 blocks, partly Elastica-van Gieson, PAS, diastase-PAS.

Microscopy

Re 1.) Tumor made up to solid structures of large atypical epithelia, densely packed in parts, with copious, mostly stained cytoplasm with the inclusion of isolated very large, otherwise often round, occasionally deformed nuclei containing granular chromatin and always prominent nucleoli. Apoptoses, not uncommonly several mitoses per markedly enlarged visual field (field length 0.61 mm). Occasionally a vague epidermoid layer, often intercellular fissures and isolated visible bridges. No mucin inclusion. In places a dissociation of the tumor cell structures. Smaller areas of necrosis. Affected lung parenchyma partly destroyed, likewise a

[page 2 of 2]
relatively a large bronchus here, strand of cartilage remaining. A further large bronchus partially infiltrated and involved in the tumor, likewise in this area smaller bronchi and bronchioles whose lumen is partly dilated, the original respiratory epithelium replaced by tumor epithelium. In adjacent region tumor cell nests and formations of small tumor lie freely in alveoli, also tumor cell structures in dilated lymph vessels. Vascularized interlobular septa, between the tumor formations partly loose, partly fiber-rich, collagenous connective tissue with accumulation of inflammatory cells. Isolated small vessels here, walls thickened by elastosis and containing tumor cells. A larger vein surrounded, loose capillary-containing fiber tissue in the lumen. Between peripheral tumor margin and visceral pleura on the medial side a strip of free lung parenchyma with partly deficient atelectasis and thickened alveolar septa. Lower pleural fissure and partly fused visceral pleura demarcating or covering this fissure transcended by tumor, where large bronchi are invaded to within close proximity of the mucosa. Large tumor node next to the upper lobe bronchus bifurcation, enclosed anthracotic pigment, tumor cell nests here at the resection margin. In the mediastinal tissue a further tumor-compromised lymph node with anthracotic pigment deposits and otherwise fibrous growth of connective tissue. In subpleural region of S1 a flat remodeling zone of the lung parenchyma with development of collagenous and elastic connective tissue, with alveolar stroma still partly recognizable. Nearby tiny radial areas of interstitial fibrosis with small patches of accumulated anthracotic pigment. In the basal lower lobe am relatively large area of nonoxygenated, fibrosed lung parenchyma with inclusion of partly obliterated smaller, partly patent vessels and bronchioles. Overlying pleura markedly enlarged and fibrotic. Otherwise here and there in dilated peripheral airways mucus and leukocytes and also a small cluster of pigment-storing macrophages in the alveoli. At the bronchus resection margin, sections of mucosal epithelium are interrupted, otherwise regular. Here as in the walls of the large pulmonary vessels no evidence of tumor cells. Lymph node at the hilus with isolated secondary follicles, slight plaque of anthracotic pigment and foci of large macrophages.

Re 2.) - b.) Partly preserved lymph nodes with few secondary follicles, varying degrees of anthracotic pigment deposits, accumulation of macrophages and isolated secondary follicles. In parts, lymph nodes are largely occupied by solid epithelial tumor. In places, tumor manifestation also in the paranodal tissue. At one point and in a larger lymph node only very small areas occupied by tumor cell nests.

EVALUATION

Primary diagnosis/diagnoses:

Central bronchopulmonary, histologically largely undifferentiated, large-cell squamous cell carcinoma of the right lower lobe of the lung (C4) with overgrowth of the interlobar fissure and continuous growth into the adjacent section of the middle lobe and also several in some cases large lymph node metastases. Tumor classification according to this picture pT2 pN3 L1 V1 R1, stage IIIB. C34.3 M8070/3.

Secondary diagnosis/diagnoses:

Peripheral bronchiolectasia in the lower lobe, relatively large fibrous cicatricial remodeling zone in S10 mediobasal and similar flat subpleural cicatricial zones in S1 apical. Local high-grade pleural fibrosis over S10. Tumor-associated inflammation and small tumor necroses. Slight anthracotic pigment deposits in the lung parenchyma and relatively marked in some lymph nodes.

Remark/addendum:

The main mass of the carcinoma lies in S10. Centrally it has grown as far as the bifurcations of the lower lobe main bronchus and the middle lobe bronchus, without these being destroyed or constricted. The tumor invasion of small blood vessels only concerns the focal region, the lymphangi invasion is more marked and is also located in the vicinity of the tumor focus. The R1 classification is based on the finding that carcinoma nests in the large involved lymph nodes next to the bifurcation of the upper lobe bronchus extend to the mediastinal resection plane. Further lymph node metastases are seen at the intermediate bronchus in the mediastinum and also in the lymph nodes located under 4.) - 6.). The pN3 classification is also made with regard to the previous finding with carcinoma cell structures in the fine needle aspiration biopsy from LN4 left (according to clinical data).

Source: NCI Genomic Data Commons file 83b7b152-a54b-4edc-9c01-142a4d4c6ca5 (TCGA-66-2791.402C71D9-26D5-4E94-82A6-6AE5EA39A391.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).